Somatic mutation profile of tumor specimen ALCH-B3FX-TTP1-A (aliquot ALCH-B3FX-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3FX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 51.0 years (18,638 days).
Specimen ALCH-B3FX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df75ff80-028b-435b-b2d1-747756adeb2a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3FX-NB1-A (Blood Derived Normal), aliquot ALCH-B3FX-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0cbef5dd-6f08-4d4c-b6c8-7c56f859fe75

The open-access MAF lists 127 somatic variants for this specimen: 80 protein-altering or splice-affecting, 34 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 34, Frame Shift Del 4, Intron 4, Nonsense Mutation 4, 5'Flank 3, 5'UTR 2, 3'UTR 2, Splice Region 1, In Frame Del 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1526G>C p.G509A (on ENST00000288602 / NM_001374244.1; = p.G469A on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/385 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- STK11 | c.169del p.E57Kfs*7 | Frame Shift Del (DEL) | VAF 92/311 reads (30%) | catalogued as rs121913319, CD044165; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BNIP5 | c.259A>G p.S87G | Missense Mutation (SNP) | VAF 52/319 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.503); catalogued as rs776296828; called by muse, mutect2, varscan2
- CARD11 | c.2902G>T p.A968S | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV67799074; called by muse, mutect2, varscan2
- CNGA3 | c.896A>G p.N299S | Missense Mutation (SNP) | VAF 88/447 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs770185966; called by muse, mutect2, varscan2
- COX7B2 | c.212G>C p.G71A | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs766001089; called by muse, mutect2, varscan2
- CSTL1 | c.422G>T p.G141V | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as COSV99851222; called by muse, mutect2, varscan2
- DUSP8 | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.412); catalogued as rs1336586462; called by muse, mutect2, varscan2
- GRHL3 | c.791G>A p.R264Q (on ENST00000350501 / NM_198174.3; = p.R269Q on NM_021180.3) | Missense Mutation (SNP) | VAF 50/321 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.897); catalogued as rs184435420, COSV99359784; called by muse, mutect2, varscan2
- LAMC3 | c.4666G>A p.D1556N | Missense Mutation (SNP) | VAF 47/186 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs147212105; called by muse, mutect2, varscan2
- LINGO2 | c.970C>G p.R324G | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as COSV58059589; called by muse, mutect2, varscan2
- MGAM | c.4508A>T p.Q1503L | Missense Mutation (SNP) | VAF 41/279 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1431952081; called by muse, mutect2, varscan2
- MMP19 | c.282G>C p.K94N | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.603); catalogued as COSV59450231, COSV59450765; called by muse, varscan2
- OR8H3 | c.14G>T p.R5M | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.258); catalogued as COSV100538804, COSV57911589; called by muse, varscan2
- PLEKHF2 | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 29/167 reads (17%) | catalogued as COSV59541957; called by muse, mutect2, varscan2
- RBM20 | c.1309G>T p.A437S | Missense Mutation (SNP) | VAF 9/213 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as rs939425427; ClinVar: uncertain significance; called by muse, mutect2
- RYR2 | c.12842C>A p.T4281K | Missense Mutation (SNP) | VAF 82/440 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV63685028; called by muse, mutect2, varscan2
- SBDS | c.731_733del p.E244del | In Frame Del (DEL) | VAF 30/184 reads (16%) | catalogued as rs779179610; called by pindel, varscan2
- SEMA3D | c.2240G>T p.G747V | Missense Mutation (SNP) | VAF 68/428 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV52394959; called by muse, mutect2, varscan2
- SLITRK4 | c.2426G>C p.S809T | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.724); catalogued as COSV62025332; called by muse, mutect2, varscan2
- SLITRK4 | c.2207C>G p.T736S | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs781923193, COSV62021899, COSV62026181; called by muse, mutect2, varscan2
- SMOX | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs145030123, COSV53865591; called by muse, mutect2
- SUV39H2 | c.767G>A p.R256Q (on ENST00000354919 / NM_001193424.2; = p.R196Q on NM_024670.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as COSV57952966; called by muse, mutect2
- TNNI3 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.372); catalogued as COSV104420835; called by muse, mutect2
- A2ML1 | c.4003A>T p.K1335* | Nonsense Mutation (SNP) | VAF 20/79 reads (25%) | called by muse, mutect2, varscan2
- ABCA13 | c.5746A>G p.T1916A | Missense Mutation (SNP) | VAF 88/392 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- AC136428.1 | c.301C>A p.Q101K | Missense Mutation (SNP) | VAF 63/278 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- AGRN | c.2805G>T p.K935N | Missense Mutation (SNP) | VAF 68/353 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AHNAK | c.13129G>T p.E4377* | Nonsense Mutation (SNP) | VAF 29/159 reads (18%) | called by muse, mutect2, varscan2
- BIRC6 | c.3944G>T p.R1315I | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC105 | c.696C>A p.D232E | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCDC151 | c.1392C>A p.D464E | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.92); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCNF | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDKL4 | c.121G>T p.D41Y | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- COL3A1 | c.3366C>A p.G1122= | Splice Region (SNP) | VAF 71/461 reads (15%) | called by muse, mutect2, varscan2
- CSMD3 | c.2149T>A p.C717S (on ENST00000297405 / NM_001363185.1; = p.C613S on NM_052900.3) | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DMRTA1 | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- DYRK2 | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 68/240 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DYSF | c.3180_3199del p.Q1061Gfs*46 | Frame Shift Del (DEL) | VAF 18/148 reads (12%) | called by mutect2, pindel, varscan2
- EFCAB6 | c.1240A>C p.I414L | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- ENTHD1 | c.712G>T p.D238Y | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- FAM237A | c.259C>A p.H87N | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FGF12 | c.329C>T p.P110L (on ENST00000454309 / NM_021032.5; = p.P48L on NM_004113.6) | Missense Mutation (SNP) | VAF 45/264 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FMN1 | c.460C>G p.H154D | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- GALP | c.226C>A p.P76T | Missense Mutation (SNP) | VAF 45/247 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GLDC | c.864C>A p.S288R | Missense Mutation (SNP) | VAF 75/336 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- GPHN | c.97G>C p.D33H | Missense Mutation (SNP) | VAF 24/388 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- IGKV1D-17 | c.228G>C p.L76F | Missense Mutation (SNP) | VAF 88/265 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- IGLV7-43 | c.5C>A p.A2D | Missense Mutation (SNP) | VAF 41/274 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- JUND | c.646G>T p.A216S | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2
- KMT2B | c.5968del p.D1990Tfs*19 | Frame Shift Del (DEL) | VAF 42/226 reads (19%) | called by mutect2, pindel*, varscan2
- MFF | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- MMP19 | c.511G>C p.D171H | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- MSLNL | c.1329G>A p.M443I | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- MUC16 | c.30253G>T p.A10085S | Missense Mutation (SNP) | VAF 28/233 reads (12%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MYO1C | c.1612G>A p.G538S (on ENST00000648651 / NM_001080779.2; = p.G503S on NM_033375.5) | Missense Mutation (SNP) | VAF 61/326 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- OR10AG1 | c.601C>A p.P201T | Missense Mutation (SNP) | VAF 40/317 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- OR11L1 | c.192G>T p.Q64H | Missense Mutation (SNP) | VAF 49/243 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- OTOGL | c.3704C>A p.T1235N (on ENST00000547103; = p.T1226N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PARP8 | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PDGFB | c.499A>T p.K167* | Nonsense Mutation (SNP) | VAF 43/263 reads (16%) | called by muse, mutect2, varscan2
- PDGFRB | c.2176C>A p.L726M | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- PPARD | c.749A>T p.Q250L | Missense Mutation (SNP) | VAF 14/366 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2
- PPP4R3C | c.1148C>A p.A383D | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PRR9 | c.213G>T p.E71D | Missense Mutation (SNP) | VAF 60/364 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPN13 | c.1721T>C p.V574A | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- ROCK1 | c.2208G>T p.Q736H | Missense Mutation (SNP) | VAF 54/209 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RP1 | c.1481G>T p.W494L | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RRAGD | c.619G>C p.A207P | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- SBSPON | c.500+1G>C p.X167_splice | Splice Site (SNP) | VAF 36/156 reads (23%) | called by muse, varscan2
- SLC2A1 | c.1096T>A p.Y366N | Missense Mutation (SNP) | VAF 68/471 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- SPTBN1 | c.2905T>A p.S969T | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TAF4 | c.1783A>G p.K595E | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- THSD7A | c.2639C>A p.A880D | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- TLL1 | c.2806_2809del p.F936Kfs*46 | Frame Shift Del (DEL) | VAF 64/417 reads (15%) | called by mutect2, pindel, varscan2
- TM6SF2 | c.968C>A p.P323H | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- UGT2B11 | c.1220A>T p.K407M | Missense Mutation (SNP) | VAF 52/403 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- UNK | c.946T>G p.F316V | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- YEATS2 | c.1967G>T p.G656V | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); called by muse, mutect2
- ZNF398 | c.743A>T p.K248M (on ENST00000475153 / NM_170686.3; = p.K77M on NM_020781.4) | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.535); called by muse, mutect2
- ABCA4 | c.372T>C p.R124= | Silent (SNP) | VAF 113/635 reads (18%) | catalogued as rs745550261; called by muse, mutect2, varscan2
- ACRV1 | c.255T>A p.S85= | Silent (SNP) | VAF 39/217 reads (18%) | called by muse, mutect2, varscan2
- ANKRD10 | c.327C>G p.V109= | Silent (SNP) | VAF 38/199 reads (19%) | called by muse, mutect2, varscan2
- CACNA1B | c.6417G>A p.P2139= | Silent (SNP) | VAF 18/218 reads (8%) | catalogued as rs763000710; called by muse, mutect2
- CALCOCO2 | c.372A>G p.Q124= | Silent (SNP) | VAF 23/172 reads (13%) | catalogued as rs1477848609; called by muse, mutect2, varscan2
- CRISP2 | c.660A>T p.T220= | Silent (SNP) | VAF 13/102 reads (13%) | called by muse, mutect2, varscan2
- DCHS2 | c.879G>T p.P293= | Silent (SNP) | VAF 34/226 reads (15%) | catalogued as rs1265823735; called by muse, mutect2, varscan2
- EFCAB6 | c.2430A>T p.P810= | Silent (SNP) | VAF 67/250 reads (27%) | called by muse, varscan2
- FAM200B | c.516T>C p.L172= | Silent (SNP) | VAF 32/246 reads (13%) | catalogued as rs1414802407; called by muse, mutect2, varscan2
- FCGBP | c.6567C>T p.F2189= | Silent (SNP) | VAF 39/1058 reads (4%) | catalogued as rs746260716, COSV55451137; called by muse, mutect2
- GCM2 | c.288T>C p.G96= | Silent (SNP) | VAF 73/473 reads (15%) | called by muse, mutect2, varscan2
- GRIP2 | c.432T>C p.T144= (on ENST00000619221; = p.T47= on NM_001080423.4) | Silent (SNP) | VAF 38/200 reads (19%) | called by muse, mutect2, varscan2
- HEATR5B | c.4245G>T p.T1415= | Silent (SNP) | VAF 16/100 reads (16%) | called by muse, mutect2, varscan2
- HERC2 | c.7605C>T p.A2535= | Silent (SNP) | VAF 23/258 reads (9%) | catalogued as rs543567383; called by muse, mutect2, varscan2
- HOXA2 | c.351C>T p.A117= | Silent (SNP) | VAF 34/210 reads (16%) | called by mutect2, varscan2
- KCP | c.3318C>A p.T1106= (on ENST00000620378; = p.T1230= on NM_001366122.1) | Silent (SNP) | VAF 16/92 reads (17%) | called by muse, mutect2, varscan2
- KIR3DL3 | c.399G>A p.L133= | Silent (SNP) | VAF 26/149 reads (17%) | called by muse, mutect2, varscan2
- KRTAP10-6 | c.552C>T p.S184= | Silent (SNP) | VAF 66/496 reads (13%) | catalogued as rs202066340; called by muse, varscan2
- LARGE2 | c.162A>T p.P54= | Silent (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- MMP19 | c.564G>A p.V188= | Silent (SNP) | VAF 40/173 reads (23%) | called by muse, mutect2, varscan2
- MYH2 | c.5046C>T p.R1682= | Silent (SNP) | VAF 71/390 reads (18%) | catalogued as rs1263766526; called by muse, mutect2, varscan2
- NANOG | c.105T>C p.Y35= | Silent (SNP) | VAF 14/314 reads (4%) | called by muse, mutect2
- NDUFA10 | c.561C>T p.Y187= | Silent (SNP) | VAF 24/370 reads (6%) | called by muse, mutect2
- NFE2L3 | c.255G>T p.A85= | Silent (SNP) | VAF 7/70 reads (10%) | called by muse, mutect2, varscan2
- OLFML2B | c.2112C>T p.T704= | Silent (SNP) | VAF 79/406 reads (19%) | catalogued as rs774082481; called by muse, mutect2, varscan2
- OR4X1 | c.90C>A p.L30= | Silent (SNP) | VAF 66/336 reads (20%) | called by muse, mutect2, varscan2
- PADI4 | c.1062C>A p.I354= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV64925209; called by mutect2, varscan2
- RASSF4 | c.267G>A p.R89= | Silent (SNP) | VAF 59/311 reads (19%) | catalogued as COSV53574299; called by muse, mutect2, varscan2
- RYR2 | c.3027G>T p.R1009= | Silent (SNP) | VAF 18/93 reads (19%) | called by muse, mutect2, varscan2
- SH3D21 | c.418C>T p.L140= (on ENST00000453908 / NM_001162530.2; = p.L29= on NM_024676.5) | Silent (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- TRRAP | c.10989G>A p.T3663= (on ENST00000359863 / NM_001244580.1; = p.T3634= on NM_003496.3) | Silent (SNP) | VAF 33/492 reads (7%) | catalogued as rs201212456; called by muse, mutect2
- UGT2B4 | c.1059G>T p.L353= | Silent (SNP) | VAF 24/171 reads (14%) | called by muse, mutect2, varscan2
- USH2A | c.13098C>A p.A4366= | Silent (SNP) | VAF 49/272 reads (18%) | catalogued as COSV100241740, COSV56352484; called by muse, mutect2, varscan2
- VAV1 | c.618G>A p.E206= | Silent (SNP) | VAF 41/208 reads (20%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130916642 A>G | 5'Flank (SNP) | VAF 27/127 reads (21%) | called by muse, mutect2, varscan2
- B4GALNT1 | chr12:57622609 C>A | 3'Flank (SNP) | VAF 43/180 reads (24%) | called by muse, mutect2, varscan2
- BCAS3 | c.2639-3357A>G | Intron (SNP) | VAF 35/173 reads (20%) | catalogued as rs1403917859, COSV66772038; called by mutect2, varscan2
- CYP11B1 | c.1122-18G>T | Intron (SNP) | VAF 40/295 reads (14%) | called by muse, mutect2, varscan2
- EMC4 | c.-55T>A | 5'UTR (SNP) | VAF 22/166 reads (13%) | called by muse, varscan2
- EPB41L4A | chr5:112419911 C>T | 5'Flank (SNP) | VAF 20/100 reads (20%) | catalogued as rs1423617905; called by muse, mutect2
- MIR520F | n.60C>T | RNA (SNP) | VAF 17/116 reads (15%) | called by muse, mutect2, varscan2
- NDRG1 | chr8:133302000 C>A | 5'Flank (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
- RAB18 | c.*3158G>C | 3'UTR (SNP) | VAF 44/341 reads (13%) | called by muse, mutect2, varscan2
- RGPD1 | c.48+5822G>T | Intron (SNP) | VAF 67/358 reads (19%) | called by muse, mutect2, varscan2
- RGS11 | c.657+483C>T | Intron (SNP) | VAF 26/147 reads (18%) | called by muse, mutect2, varscan2
- RGS4 | c.-75T>A | 5'UTR (SNP) | VAF 51/350 reads (15%) | called by muse, mutect2, varscan2
- SLC37A3 | c.*57C>T | 3'UTR (SNP) | VAF 22/416 reads (5%) | catalogued as rs372795507; called by muse, mutect2
